Somatic mutation profile of tumor specimen MP2PRT-PAPZKX-TMP1-A (aliquot MP2PRT-PAPZKX-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZKX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (994 days).
Specimen MP2PRT-PAPZKX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03d3f529-ac4a-4e40-974e-2d2167570c32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZKX-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZKX-NB1-B-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28c37d05-891e-4895-ad27-3d188620ae16

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DACH2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs749449951, COSV64174796; called by mutect2, varscan2
- SLC25A31 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.669); catalogued as rs1006044667, COSV55421888, COSV55421946; called by muse, mutect2
- TARM1 | c.794G>A p.S265N (on ENST00000616041 / NM_001330650.1; = p.S257N on NM_001135686.3) | Missense Mutation (SNP) | VAF 29/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1415356423; called by muse, mutect2
- CATSPERB | c.2203T>C p.Y735H | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RUSC2 | c.4064A>G p.E1355G | Missense Mutation (SNP) | VAF 16/542 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- OR2G2 | c.546C>T p.C182= | Silent (SNP) | VAF 68/309 reads (22%) | catalogued as rs146695930; called by muse, mutect2, varscan2
- TMPRSS11D | c.810A>G p.E270= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
